Somatic mutation profile of tumor specimen TCGA-BR-8080-01A (aliquot TCGA-BR-8080-01A-11D-2340-08) from TCGA case TCGA-BR-8080, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.7 years (26,546 days).
Specimen TCGA-BR-8080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a0590ef-f7c0-4353-a0df-d215930a7d42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8080-10A (Blood Derived Normal), aliquot TCGA-BR-8080-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9af931-de52-4067-ab91-02e6cbe772f9

The open-access MAF lists 164 somatic variants for this specimen: 126 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 35, Nonsense Mutation 7, Intron 1, Frame Shift Del 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOGL | c.5027C>G p.S1676* (on ENST00000547103; = p.S1667* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/205 reads (11%) | catalogued as rs1477766714, COSV100087340, COSV54015249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 33/139 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- ACHE | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99574178; called by muse, mutect2, varscan2
- ADCY2 | c.3116A>G p.K1039R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV57895686; called by muse, mutect2
- ADGRL2 | c.1844A>T p.N615I (on ENST00000370717 / NM_001366005.1; = p.N602I on NM_012302.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54685693, COSV99592357; called by muse, mutect2, varscan2
- AGA | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747683614, COSV52807488; called by muse, mutect2
- AGK | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62595790; called by muse, mutect2, varscan2
- ALAS2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV58192949; called by muse, mutect2, varscan2
- AMOTL2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1487351364, COSV51440255; called by muse, mutect2
- ARSD | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs760383834, COSV99472175; called by muse, mutect2, varscan2
- ASPM | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.408); catalogued as COSV54137281; called by muse, mutect2
- ASXL3 | c.4981G>A p.V1661I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52461786; called by muse, mutect2, varscan2
- BAHD1 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.251); catalogued as rs768466577, COSV69084588; called by muse, mutect2
- BCAS1 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.215); catalogued as rs1177431410, COSV65088972; called by muse, mutect2
- BTBD10 | c.414T>G p.S138R | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.136); catalogued as COSV53401127, COSV99533507; called by muse, mutect2
- BTN1A1 | c.1127G>T p.R376M | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV55069390; called by muse, mutect2, varscan2
- CAMK4 | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56674182; called by muse, mutect2, varscan2
- CAND1 | c.2900T>G p.L967R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101607323; called by muse, mutect2, varscan2
- CARD8 | c.844G>T p.A282S (on ENST00000651546 / NM_001184900.3; = p.A232S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62874329, COSV62875022; called by muse, mutect2, varscan2
- CCDC89 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57034779; called by muse, mutect2
- CD163 | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 23/176 reads (13%) | catalogued as COSV63129153, COSV63136586; called by muse, mutect2, varscan2
- CDH7 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59893268; called by muse, mutect2
- CDH7 | c.2135G>T p.W712L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.551); catalogued as COSV59893281; called by muse, mutect2
- CNGA2 | c.1289A>G p.K430R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV61706038; called by muse, mutect2, varscan2
- COLEC12 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138304922; called by muse, mutect2, varscan2
- CPA6 | c.569G>C p.W190S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV99913738; called by muse, mutect2, varscan2
- CRISPLD1 | c.1284T>A p.H428Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV51552503; called by muse, mutect2
- CSMD1 | c.8675T>A p.L2892H (on ENST00000520002; = p.L2891H on NM_033225.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59374563; called by muse, mutect2, varscan2
- CSMD3 | c.5471A>G p.Q1824R (on ENST00000297405 / NM_001363185.1; = p.Q1720R on NM_052900.3) | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV104398491, COSV52297249; called by muse, mutect2
- CSMD3 | c.3764C>T p.P1255L (on ENST00000297405 / NM_001363185.1; = p.P1151L on NM_052900.3) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285875; called by muse, mutect2
- CTNND2 | c.2944C>T p.R982W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs760214222, COSV58871869; called by muse, mutect2, varscan2
- CUBN | c.9084C>G p.F3028L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV64725365; called by muse, mutect2, varscan2
- CXCL9 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV53579622; called by muse, mutect2
- DLGAP1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs755918617, COSV59831048; called by muse, mutect2, varscan2
- DMD | c.8407A>G p.S2803G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV58946846; called by muse, mutect2, varscan2
- DNMT3B | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs1226308460, COSV52416376; called by muse, mutect2
- DPP10 | c.877A>T p.K293* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV59718920; called by muse, mutect2
- EDNRA | c.314T>G p.I105S | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60100150; called by muse, mutect2, varscan2
- EIF2AK1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as COSV52242607; called by muse, mutect2, varscan2
- ESRRG | c.925T>G p.L309V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1206734214, COSV63177915; called by muse, mutect2
- EZHIP | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs782520788, COSV100539575, COSV57955400, COSV57956449; called by muse, mutect2
- FLNB | c.3606C>G p.Y1202* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV55893395; called by muse, mutect2, varscan2
- FLRT2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs751520518, COSV58143981, COSV58144150; called by muse, mutect2, varscan2
- FMR1NB | c.519T>G p.C173W | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63272983; called by muse, mutect2, varscan2
- GAK | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV58508854; called by muse, mutect2, varscan2
- GLRB | c.223T>G p.F75V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52421665; called by muse, mutect2
- GRID2 | c.883A>C p.S295R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.604); catalogued as COSV56178862; called by muse, mutect2, varscan2
- GRXCR1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs570302879, COSV67671883; called by muse, mutect2
- HAPLN1 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.881); catalogued as rs1016662307, COSV57151412; called by muse, mutect2
- HAPLN3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs770255399, COSV61368197; called by muse, mutect2
- IGLV1-40 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs529794117; called by muse, mutect2, varscan2
- IL7 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99805327; called by muse, mutect2
- ING2 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56564585; called by muse, mutect2
- JAKMIP2 | c.1534C>A p.Q512K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV54603659, COSV54614101; called by muse, mutect2
- JMY | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68662194; called by muse, mutect2
- LAMA2 | c.8327T>C p.I2776T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV101370514; called by muse, mutect2
- LRP1B | c.13544T>G p.M4515R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV67266780; called by muse, mutect2
- LRP1B | c.12062T>C p.L4021P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67190256, COSV67266785; called by muse, mutect2
- LRRC32 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV52635158; called by muse, mutect2
- LRTM1 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.258); catalogued as COSV55575044, COSV99835891; called by muse, mutect2, varscan2
- MAMLD1 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV53373136; called by muse, mutect2
- MAP3K15 | c.2379T>G p.F793L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100134861; called by muse, mutect2
- MATR3 | c.2114G>A p.S705N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV63079480; called by muse, mutect2, varscan2
- MKRN3 | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58811904; called by muse, mutect2, varscan2
- MUC16 | c.4000A>G p.S1334G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101199725, COSV67489104; called by muse, mutect2, varscan2
- MYBPH | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55139931; called by muse, mutect2
- MYF6 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57353064; called by muse, mutect2, varscan2
- MYO3A | c.4182T>A p.Y1394* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV56340314; called by muse, mutect2
- NALCN | c.4576G>A p.G1526S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.465); catalogued as rs754064797, COSV51961136; called by muse, mutect2, varscan2
- NALCN | c.3253T>C p.W1085R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV51961155; called by muse, mutect2, varscan2
- NDNF | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV101113270, COSV65632414, COSV65634573; called by muse, mutect2
- NOMO1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1387287870, COSV99814570; called by mutect2, varscan2
- NPTX2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs769298573, COSV55716138; called by muse, mutect2
- OR13F1 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 14/129 reads (11%) | catalogued as COSV58252549; called by muse, mutect2, varscan2
- OR2AG2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV58456051; called by muse, mutect2, varscan2
- OR4P4 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58923385; called by muse, mutect2
- OR51D1 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62914774; called by muse, mutect2
- OR52N1 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57693950, COSV57693989; called by muse, mutect2
- OR5H14 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs777550264, COSV71194498; called by muse, mutect2, varscan2
- OR8U1 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100163932; called by muse, mutect2
- PCBP1 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57851745; called by muse, mutect2
- PCDH7 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.34); catalogued as COSV62342911; called by muse, mutect2, varscan2
- PCDHA13 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as rs200938440, COSV56488325, COSV56489998; called by muse, mutect2, varscan2
- PCDHB11 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as COSV53382514; called by muse, mutect2, varscan2
- PCNX3 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs754145730, COSV63140322; called by muse, mutect2, varscan2
- PKM | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58791395; called by muse, mutect2
- PLEKHG4B | c.1241C>T p.A414V (on ENST00000283426; = p.A770V on NM_052909.5) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs1048844543, COSV52043518, COSV52054025; called by muse, mutect2
- PTOV1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776677018, COSV55590304; called by muse, mutect2
- PTPRC | c.2691A>C p.Q897H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61405854, COSV61412086, COSV61419400; called by muse, mutect2
- PXDNL | c.817T>G p.S273A | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100684090, COSV62479258; called by muse, mutect2
- RAB40A | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV58492011; called by muse, mutect2, varscan2
- RAPGEF2 | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52433038; called by muse, mutect2
- RARS2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV65762428; called by muse, mutect2
- SALL1 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as COSV51763632; called by muse, mutect2, varscan2
- SCN3A | c.1649A>G p.K550R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV51822014; called by muse, mutect2, varscan2
- SERPINA5 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs1184655353, COSV61574918; called by muse, mutect2
- SLIT2 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99884338; called by muse, mutect2
- SLITRK4 | c.2045G>T p.S682I | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV62025845; called by muse, mutect2, varscan2
- SOS2 | c.346-1G>A p.X116_splice | Splice Site (SNP) | VAF 21/92 reads (23%) | catalogued as COSV53573581; called by muse, mutect2, varscan2
- SP1 | c.1504C>G p.L502V (on ENST00000327443 / NM_138473.3; = p.L495V on NM_003109.1) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.581); catalogued as COSV59405017; called by muse, mutect2
- SPTA1 | c.5848A>C p.S1950R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.648); catalogued as COSV63758274; called by muse, mutect2, varscan2
- SSH2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV52179942; called by muse, mutect2
- SULT1A2 | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as rs530005107, COSV57682933; called by muse, mutect2, varscan2
- SYT4 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54898331, COSV99673890; called by muse, mutect2
- SYT9 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV59624098; called by muse, mutect2, varscan2
- TP53 | c.1033A>G p.N345D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53531433, COSV53637240; called by muse, mutect2, varscan2
- TRAF6 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61923470; called by muse, mutect2, varscan2
- TRAF7 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs200505184, COSV58217999; called by muse, mutect2, varscan2
- TRIM6 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53478668; called by muse, mutect2
- TRPC5 | c.774A>C p.Q258H | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.533); catalogued as COSV53301567; called by muse, mutect2
- TTN | c.66749T>C p.L22250P (on ENST00000591111; = p.L14826P on NM_003319.4) | Missense Mutation (SNP) | VAF 33/421 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60299512, COSV60317881; called by muse, mutect2
- TTN | c.13642T>C p.Y4548H (on ENST00000591111; = p.Y3621H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV60299528; called by muse, mutect2, varscan2
- UGT3A1 | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV99954825; called by muse, mutect2
- UNC79 | c.4891T>G p.S1631A (on ENST00000393151 / NM_001346218.2; = p.S1454A on NM_020818.5) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV56407057; called by muse, mutect2, varscan2
- WDR17 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV54582190; called by muse, mutect2
- ZHX3 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs372943167; called by muse, mutect2, varscan2
- ZNF12 | c.951A>C p.R317S (on ENST00000405858 / NM_016265.4; = p.R279S on NM_006956.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61245449; called by muse, mutect2, varscan2
- ZNF135 | c.755G>A p.R252Q (on ENST00000313434 / NM_001289401.2; = p.R264Q on NM_003436.4) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.865); catalogued as rs769862321, COSV57882521; called by muse, mutect2
- ZNF208 | c.2455A>T p.T819S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV68099862, COSV68101018; called by muse, mutect2, varscan2
- ZNF534 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV56520543; called by muse, mutect2, varscan2
- ZNF875 | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.166); catalogued as COSV60993454; called by muse, mutect2, varscan2
- ZP4 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100850694; called by muse, mutect2
- IGHV3-11 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TIA1 | c.533G>A p.R178K (on ENST00000433529 / NM_001351511.1; = p.R167K on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2
- TRPV5 | c.8del p.G3Vfs*43 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ACOT4 | c.510C>T p.L170= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV58335442, COSV58336267; called by muse, mutect2, varscan2
- ARSD | c.1317C>T p.S439= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99472173; called by muse, mutect2, varscan2
- BBS4 | c.903C>G p.P301= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV51439928; called by muse, mutect2, varscan2
- BEND3 | c.2142G>A p.P714= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as rs534703055, COSV64682120; called by muse, mutect2
- CCDC178 | c.1251A>T p.A417= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV55793978; called by muse, mutect2
- CCN3 | c.232C>T p.L78= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99423014; called by muse, mutect2
- CD1C | c.279T>C p.F93= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV63807411; called by muse, mutect2, varscan2
- CERS2 | c.243C>T p.N81= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs143495079, COSV54994111; called by muse, mutect2, varscan2
- CNTNAP4 | c.2961T>G p.T987= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56697877; called by muse, mutect2, varscan2
- DBH | c.561C>T p.G187= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55042211; called by mutect2, varscan2
- FOXK1 | c.1740G>A p.A580= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs780896615, COSV61068324; called by muse, mutect2
- HOXD10 | c.165G>A p.P55= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1438215691, COSV50898406; called by muse, mutect2
- IGLV1-44 | c.291G>A p.G97= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as rs529103938; called by muse, mutect2, varscan2
- IQGAP3 | c.1383C>T p.G461= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1251452496, COSV63254208; called by muse, mutect2
- LMX1A | c.555T>C p.T185= | Silent (SNP) | VAF 11/192 reads (6%) | catalogued as COSV54220942, COSV54222735; called by muse, mutect2
- MEIOC | c.1251C>A p.G417= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100740246; called by muse, mutect2
- NLRP7 | c.2079G>T p.R693= (on ENST00000340844 / NM_206828.3; = p.R665= on NM_139176.3) | Silent (SNP) | VAF 26/271 reads (10%) | catalogued as rs748992976, COSV60180994; called by muse, mutect2, varscan2
- OAS1 | c.393G>A p.A131= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs147639145, COSV52538279; called by muse, mutect2, varscan2
- OR10G7 | c.891T>G p.A297= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57868728; called by muse, mutect2, varscan2
- PCDHB3 | c.735G>T p.P245= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV50568772, COSV50622650; called by muse, mutect2
- PGR | c.618C>T p.S206= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs758063171, COSV54809592; called by muse, mutect2, varscan2
- PLG | c.1200T>C p.S400= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV51985963; called by muse, mutect2, varscan2
- POU4F1 | c.948G>A p.T316= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV65885012; called by muse, mutect2
- PREX2 | c.1932T>A p.V644= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV55796116; called by muse, mutect2
- PROKR2 | c.342C>T p.Y114= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1454126445, COSV54085714; called by muse, mutect2, varscan2
- PSD2 | c.312G>T p.L104= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99217242; called by muse, mutect2, varscan2
- PSG4 | c.1065C>T p.F355= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as rs750645663, COSV54935579; called by muse, mutect2, varscan2
- RGS22 | c.3039C>A p.I1013= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1355954304, COSV62666737; called by muse, mutect2
- SMG6 | c.1206G>T p.R402= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV53974116; called by muse, mutect2
- SORBS1 | c.1602C>T p.S534= (on ENST00000361941 / NM_001034954.2; = p.S324= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs529818287, COSV53364364; called by muse, mutect2, varscan2
- TCEAL6 | c.486T>C p.F162= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV101035970; called by muse, mutect2
- TLE4 | c.985C>A p.R329= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1398340516, COSV54640204; called by muse, mutect2
- USP29 | c.1584A>G p.Q528= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as rs772113885, COSV54146131; called by muse, mutect2, varscan2
- VCAN | c.7416A>G p.P2472= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV54115061; called by muse, mutect2, varscan2
- ZDBF2 | c.3591T>C p.S1197= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100985644, COSV65629498; called by muse, mutect2
- AC073310.1 | n.444C>A | RNA (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 14/64 reads (22%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- KIF1B | c.2115+6628G>T | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as COSV55807579; called by muse, mutect2
